Somatic mutation profile of tumor specimen 0DLX57 from CCDI case PBBZPR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Middle ear; Age at diagnosis: 5.4 years (1,986 days).
Specimen 0DLX57: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18d37e07-4d5c-44be-ada4-2f236212d1be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d98d5d37-4cdc-4eab-94f9-0e83226d5608

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 7, Intron 5, Nonsense Mutation 4, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 310/716 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519792, COSV52800481, COSV52801581; ClinVar: likely pathogenic; called by muse, varscan2
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 434/930 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, varscan2
- ABRA | c.930G>T p.M310I | Missense Mutation (SNP) | VAF 224/1350 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61733281; called by muse, varscan2
- ANXA10 | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 281/1072 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63738440; called by muse, varscan2
- CHST10 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 148/820 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751375820, COSV51804243; called by muse, varscan2
- CYSLTR1 | c.1003T>C p.C335R | Missense Mutation (SNP) | VAF 258/566 reads (46%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.009); catalogued as rs764083500; called by muse, varscan2
- DCAF4L2 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 136/1002 reads (14%) | catalogued as COSV60476493; called by muse, varscan2
- FBXO41 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs748915973; called by muse, varscan2
- FN1 | c.6745+2T>G p.X2249_splice (on ENST00000359671 / NM_001365524.2; = p.X2218_splice on NM_002026.4) | Splice Site (SNP) | VAF 132/759 reads (17%) | catalogued as COSV60566000; called by muse, varscan2
- GCC2 | c.2627A>C p.Q876P | Missense Mutation (SNP) | VAF 282/1694 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100565654; called by muse, varscan2
- MON2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 244/1691 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755801169, COSV54810110; called by muse, varscan2
- NWD1 | c.2493C>A p.C831* | Nonsense Mutation (SNP) | VAF 88/442 reads (20%) | catalogued as COSV60340893; called by muse, varscan2
- PADI4 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 100/420 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.093); catalogued as COSV64924223; called by muse, varscan2
- RBL1 | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 238/1424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1307982606; called by muse, varscan2
- SLC13A2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 102/406 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373529809; called by muse, varscan2
- ZNF804A | c.2194T>C p.C732R | Missense Mutation (SNP) | VAF 279/1620 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs761667409; called by muse, varscan2
- ACTL7B | c.843C>G p.Y281* | Nonsense Mutation (SNP) | VAF 124/468 reads (26%) | called by muse, varscan2
- AUTS2 | c.660+1G>A p.X220_splice | Splice Site (SNP) | VAF 142/931 reads (15%) | called by muse, varscan2
- BIRC6 | c.14342G>A p.S4781N | Missense Mutation (SNP) | VAF 255/1411 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); called by muse, varscan2
- CADPS | c.851A>C p.K284T | Missense Mutation (SNP) | VAF 186/855 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- CRTC3 | c.932C>A p.A311D | Missense Mutation (SNP) | VAF 114/520 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, varscan2
- DNAI2 | c.1772C>A p.A591E | Missense Mutation (SNP) | VAF 247/647 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, varscan2
- FAM205A | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 66/356 reads (19%) | called by muse, varscan2
- FLNC | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 154/754 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- FOXA3 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- GAS7 | c.967G>T p.A323S (on ENST00000432992 / NM_201433.2; = p.A183S on NM_003644.3) | Missense Mutation (SNP) | VAF 193/790 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, varscan2
- GUCA1B | c.259A>T p.R87W | Missense Mutation (SNP) | VAF 112/536 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, varscan2
- IQSEC2 | c.2533C>T p.R845W (on ENST00000642864 / NM_001111125.3; = p.R640W on NM_015075.2) | Missense Mutation (SNP) | VAF 176/386 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- LRRC4 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 74/408 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.371); called by muse, varscan2
- MDH1B | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 242/1546 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, varscan2
- NR2C1 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 132/910 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, varscan2
- OTC | c.761C>G p.A254G | Missense Mutation (SNP) | VAF 205/448 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, varscan2
- PAX1 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 114/569 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- PCDHA4 | c.2087T>A p.V696D | Missense Mutation (SNP) | VAF 78/468 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, varscan2
- PCDHGA12 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 194/1048 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- RNF213 | c.2747A>G p.E916G | Missense Mutation (SNP) | VAF 191/1038 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, varscan2
- SATB1 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 302/1322 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, varscan2
- SGTB | c.685G>C p.A229P | Missense Mutation (SNP) | VAF 188/1226 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, varscan2
- SYNDIG1 | c.525G>C p.M175I | Missense Mutation (SNP) | VAF 184/974 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- TANGO6 | c.2368G>T p.V790L | Missense Mutation (SNP) | VAF 160/726 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, varscan2
- TAP2 | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, varscan2
- TRIP11 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 180/1052 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.093); called by muse, varscan2
- WDR70 | c.206G>C p.R69T | Missense Mutation (SNP) | VAF 148/922 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, varscan2
- ZNF775 | c.767G>T p.C256F | Missense Mutation (SNP) | VAF 50/361 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); called by muse, varscan2
- DNAH11 | c.11232C>A p.I3744= | Silent (SNP) | VAF 134/820 reads (16%) | catalogued as rs201120788, COSV60966907; called by muse, varscan2
- FUT6 | c.768C>T p.T256= | Silent (SNP) | VAF 51/446 reads (11%) | catalogued as rs764411477, COSV54605099; called by muse, varscan2
- GDPD4 | c.462A>G p.V154= | Silent (SNP) | VAF 276/1782 reads (15%) | called by muse, varscan2
- NOX4 | c.114C>T p.N38= | Silent (SNP) | VAF 169/1336 reads (13%) | called by muse, varscan2
- SLC45A1 | c.27G>A p.P9= | Silent (SNP) | VAF 112/509 reads (22%) | catalogued as rs746109782, COSV57096568, COSV99239282; called by muse, varscan2
- TIGD3 | c.558C>T p.P186= | Silent (SNP) | VAF 60/402 reads (15%) | catalogued as rs368003412; called by muse, varscan2
- YARS2 | c.1431G>A p.L477= | Silent (SNP) | VAF 142/1217 reads (12%) | called by muse, varscan2
- EYS | c.1766+2597C>G | Intron (SNP) | VAF 216/1270 reads (17%) | called by muse, varscan2
- KMT2A | c.5549-35C>A | Intron (SNP) | VAF 111/884 reads (13%) | called by muse, varscan2
- MOB2 | c.169+28C>A | Intron (SNP) | VAF 20/170 reads (12%) | called by muse, varscan2
- NKAIN3 | c.533-24738G>A | Intron (SNP) | VAF 148/1070 reads (14%) | catalogued as rs1224068616; called by muse, varscan2
- NOP2 | c.1560+54C>G | Intron (SNP) | VAF 42/334 reads (13%) | called by muse, varscan2
- ZNF84 | c.*75A>G | 3'UTR (SNP) | VAF 46/253 reads (18%) | called by muse, varscan2
